CCDI case PBCMXN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0a01d423-7cb6-40fb-94e1-992a3e1ddd39

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,722 days).

Biospecimens (3 samples)
- Sample 0DVJNV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJO7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVJOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
